Somatic mutation profile of tumor specimen C3N-06053-02 (aliquot CPT0439120006) from CPTAC case C3N-06053, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIID; Age at diagnosis: 89.1 years (32,550 days).
Specimen C3N-06053-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6cf8872-6dfd-4001-a62c-a865f63e3c1e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-06053-31 (Blood Derived Normal), aliquot CPT0444890005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ae07992-2e7b-42ae-9ed1-76693ed8fd4d

The open-access MAF lists 182 somatic variants for this specimen: 117 protein-altering or splice-affecting, 62 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 62, Nonsense Mutation 7, Splice Region 3, Frame Shift Ins 2, Frame Shift Del 2, 5'Flank 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1745C>T p.S582L (on ENST00000281708 / NM_001349798.2; = p.S502L on NM_018315.5) | Missense Mutation (SNP) | VAF 144/392 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV104381731, COSV55890836; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 306/451 reads (68%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 155/257 reads (60%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 159/414 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV50968367; called by muse, mutect2, varscan2
- ADGRL3 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 160/441 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1459120503; called by muse, mutect2, varscan2
- ADGRV1 | c.5815G>A p.E1939K | Missense Mutation (SNP) | VAF 193/322 reads (60%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as rs767740072, COSV67979441; called by muse, mutect2, varscan2
- AIM2 | c.156G>A p.M52I | Missense Mutation (SNP) | VAF 73/635 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV100931125; called by muse, mutect2, varscan2
- AK9 | c.2978G>A p.R993K | Missense Mutation (SNP) | VAF 100/273 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58143255; called by muse, mutect2, varscan2
- ALOXE3 | c.468G>C p.M156I | Missense Mutation (SNP) | VAF 153/279 reads (55%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100559596; called by muse, mutect2, varscan2
- ANKEF1 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 161/436 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV65693748; called by muse, mutect2, varscan2
- ANXA4 | c.96C>T p.L32= | Splice Region (SNP) | VAF 104/298 reads (35%) | catalogued as rs187492712; called by muse, mutect2, varscan2
- ARMC5 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 173/543 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs549433680, COSV51657368; called by muse, mutect2, varscan2
- BMP5 | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 168/515 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV63702148; called by muse, mutect2, varscan2
- CACNA1A | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 121/315 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64191217; called by muse, mutect2, varscan2
- CADM2 | c.599C>T p.A200V (on ENST00000407528 / NM_001167674.2; = p.A202V on NM_153184.4) | Missense Mutation (SNP) | VAF 133/336 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs934666245, COSV67371559; called by muse, varscan2
- CCDC116 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 199/993 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140424879; called by muse, mutect2, varscan2
- CCDC171 | c.2075A>C p.N692T | Missense Mutation (SNP) | VAF 96/163 reads (59%) | SIFT tolerated (0.46); PolyPhen benign (0.306); catalogued as COSV52642014; called by muse, mutect2, varscan2
- CILP | c.3104G>A p.R1035Q | Missense Mutation (SNP) | VAF 217/592 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs905659869; called by muse, mutect2, varscan2
- CNTNAP4 | c.1277G>A p.G426E | Missense Mutation (SNP) | VAF 161/451 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1269995753, COSV56667147, COSV56699877; called by muse, mutect2, varscan2
- CREBBP | c.5987C>T p.A1996V | Missense Mutation (SNP) | VAF 227/675 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as COSV99269726; called by muse, mutect2, varscan2
- FGD6 | c.1812A>T p.K604N | Missense Mutation (SNP) | VAF 180/402 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs940102795; called by muse, mutect2, varscan2
- FRAT1 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 139/448 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.931); catalogued as rs1353453869; called by muse, mutect2, varscan2
- FREM2 | c.1853C>T p.P618L | Missense Mutation (SNP) | VAF 174/514 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54838523; called by muse, mutect2, varscan2
- FRMPD1 | c.4151G>A p.R1384Q | Missense Mutation (SNP) | VAF 238/446 reads (53%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.84); catalogued as rs777791640, COSV66699619; called by muse, mutect2, varscan2
- GABRA6 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 95/205 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs377669113; called by muse, mutect2, varscan2
- GLRA2 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 261/353 reads (74%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as rs1023383061, COSV54336173; called by muse, mutect2, varscan2
- GPC6 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 179/450 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1441732321, COSV100989842; called by muse, mutect2, varscan2
- HCN1 | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 164/299 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as COSV100302027, COSV57513641; called by muse, mutect2, varscan2
- HTR1A | c.509C>A p.P170Q | Missense Mutation (SNP) | VAF 36/408 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60502900, COSV60503103; called by muse, mutect2
- ITGA1 | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 133/253 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140779034; called by muse, mutect2, varscan2
- KIAA0408 | c.1340G>A p.R447K | Missense Mutation (SNP) | VAF 154/392 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs267600792; called by muse, mutect2, varscan2
- LAMA2 | c.3086G>A p.R1029Q | Missense Mutation (SNP) | VAF 102/347 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs149993931; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LMX1A | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 220/595 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764888037, COSV54218729; called by muse, mutect2, varscan2
- MTUS2 | c.2242C>T p.P748S | Missense Mutation (SNP) | VAF 124/343 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); catalogued as rs750000922, COSV70920255; called by muse, mutect2, varscan2
- MUC16 | c.3064C>T p.L1022F | Missense Mutation (SNP) | VAF 220/734 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs370464728; called by muse, mutect2
- NUP50 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 45/617 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs1006110340; called by muse, mutect2
- NYAP1 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 217/621 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs771478936, COSV100278690; called by muse, mutect2, varscan2
- ONECUT2 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 161/451 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as rs954601926, COSV72152977; called by muse, mutect2, varscan2
- OR10AC1 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 244/716 reads (34%) | SIFT tolerated, low confidence (0.34); catalogued as rs769126272; called by muse, mutect2, varscan2
- OR5H14 | c.643C>T p.L215F | Missense Mutation (SNP) | VAF 69/185 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.163); catalogued as rs1240000589, COSV71193776; called by muse, mutect2, varscan2
- OR5K3 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 121/302 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV67349994; called by muse, varscan2
- OTOP1 | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 163/461 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1460426057; called by muse, mutect2, varscan2
- PCDHB7 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 166/300 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554280037; called by muse, mutect2, varscan2
- PLCZ1 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 98/261 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as rs1308051972, COSV56855967; called by muse, mutect2, varscan2
- PLS1 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 95/456 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs745917265; called by muse, mutect2, varscan2
- PXDNL | c.2708C>T p.S903L | Missense Mutation (SNP) | VAF 177/492 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.871); catalogued as COSV62494409; called by muse, mutect2, varscan2
- RASGRP4 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 155/423 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1173902608, COSV53095700; called by muse, mutect2, varscan2
- RASSF1 | c.730C>T p.R244C (on ENST00000357043 / NM_170714.2; = p.R240C on NM_007182.5) | Missense Mutation (SNP) | VAF 99/426 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as rs754586222; called by muse, mutect2, varscan2
- RSAD1 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 248/662 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1022041686; called by muse, mutect2
- RTL1 | c.3193G>A p.A1065T | Missense Mutation (SNP) | VAF 199/388 reads (51%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs988429045; called by muse, mutect2, varscan2
- SERPINB4 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 128/360 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs1272828136, COSV100345644; called by muse, mutect2, varscan2
- SH3RF3 | c.2350G>A p.G784S | Missense Mutation (SNP) | VAF 239/646 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.109); catalogued as rs1400986470; called by muse, mutect2, varscan2
- SLC22A24 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 124/335 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV70302859; called by muse, mutect2, varscan2
- SLC30A3 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 160/404 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as rs956968053, COSV51984161, COSV99273551; called by muse, mutect2, varscan2
- SORL1 | c.3913G>A p.G1305R | Missense Mutation (SNP) | VAF 90/267 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs763582192; called by muse, mutect2, varscan2
- TMEM200A | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 192/555 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs754474838, COSV51658297; called by muse, mutect2, varscan2
- TTN | c.25401G>A p.W8467* (on ENST00000591111; = p.W7540* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 177/516 reads (34%) | catalogued as COSV100612318; called by muse, mutect2, varscan2
- TTN | c.25400G>A p.W8467* (on ENST00000591111; = p.W7540* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 176/513 reads (34%) | catalogued as COSV59876824; called by muse, mutect2, varscan2
- USP17L1 | c.1047G>A p.M349I | Missense Mutation (SNP) | VAF 206/584 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs759584446; called by muse, mutect2, varscan2
- ABHD12B | c.770C>T p.P257L (on ENST00000337334 / NM_001206673.2; = p.P180L on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 123/212 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- ADH1A | c.831G>A p.M277I | Missense Mutation (SNP) | VAF 136/394 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATAD2B | c.1558C>T p.Q520* | Nonsense Mutation (SNP) | VAF 96/339 reads (28%) | called by muse, mutect2
- BBX | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 94/274 reads (34%) | called by muse, mutect2, varscan2
- CADM3 | c.220G>A p.E74K (on ENST00000368125 / NM_001127173.3; = p.E108K on NM_021189.5) | Missense Mutation (SNP) | VAF 86/300 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- CCDC117 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 93/167 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CCN5 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 219/584 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CFAP54 | c.4518G>A p.M1506I | Missense Mutation (SNP) | VAF 58/284 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CNTN6 | c.2917G>A p.E973K | Missense Mutation (SNP) | VAF 45/295 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- COL11A2 | c.3187G>A p.G1063R (on ENST00000341947 / NM_080680.3; = p.G956R on NM_080679.2) | Missense Mutation (SNP) | VAF 211/679 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL3A1 | c.2390C>T p.P797L | Missense Mutation (SNP) | VAF 125/397 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CPHXL | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 191/602 reads (32%) | called by muse, mutect2, varscan2
- DENND4B | c.3621C>T p.P1207= | Splice Region (SNP) | VAF 170/486 reads (35%) | called by muse, mutect2, varscan2
- ELFN2 | c.1418dup p.S475Lfs*46 | Frame Shift Ins (INS) | VAF 252/760 reads (33%) | called by mutect2, pindel, varscan2
- EVPLL | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 168/297 reads (57%) | SIFT tolerated (0.58); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- FGD5 | c.4140G>A p.W1380* | Nonsense Mutation (SNP) | VAF 129/300 reads (43%) | called by muse, mutect2, varscan2
- FMN2 | c.3668C>T p.P1223L | Missense Mutation (SNP) | VAF 201/505 reads (40%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GRIA4 | c.1122G>A p.M374I | Missense Mutation (SNP) | VAF 112/346 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HERC1 | c.13258C>T p.L4420F | Missense Mutation (SNP) | VAF 97/335 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HMGA2 | c.55_77del p.P19Efs*16 | Frame Shift Del (DEL) | VAF 62/444 reads (14%) | called by mutect2, pindel
- IGSF9B | c.2284C>T p.P762S | Missense Mutation (SNP) | VAF 140/414 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- IL2RG | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 228/349 reads (65%) | SIFT tolerated (0.16); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- KMT2A | c.7293dup p.S2432Ifs*3 | Frame Shift Ins (INS) | VAF 99/356 reads (28%) | called by mutect2, pindel, varscan2
- LYPLA2 | c.463T>A p.F155I | Missense Mutation (SNP) | VAF 430/629 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- METTL16 | c.776A>C p.K259T | Missense Mutation (SNP) | VAF 135/241 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- MITF | c.1009C>T p.P337S (on ENST00000448226 / NM_006722.3; = p.P237S on NM_000248.4) | Missense Mutation (SNP) | VAF 87/218 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- NCR1 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 277/750 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- NEXMIF | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 209/288 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NQO2 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 143/441 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- OR2M2 | c.593T>C p.V198A | Missense Mutation (SNP) | VAF 188/512 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PAXIP1 | c.851G>C p.G284A | Missense Mutation (SNP) | VAF 177/475 reads (37%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PICK1 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 165/779 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- PIK3R5 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 180/337 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PIP5K1A | c.1159C>T p.P387S (on ENST00000368888 / NM_001135638.2; = p.P374S on NM_003557.3) | Missense Mutation (SNP) | VAF 135/325 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- PITPNM2 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 106/293 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLCL1 | c.1456C>G p.P486A | Missense Mutation (SNP) | VAF 78/520 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRR12 | c.51+6C>T | Splice Region (SNP) | VAF 243/634 reads (38%) | called by muse, mutect2, varscan2
- PRSS58 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 173/524 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAB3GAP2 | c.3182T>C p.F1061S | Missense Mutation (SNP) | VAF 131/376 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RGPD3 | c.3470C>T p.A1157V | Missense Mutation (SNP) | VAF 212/711 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- RIOK3 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 106/348 reads (30%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SAMD3 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 153/390 reads (39%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SCG2 | c.1043T>A p.I348N | Missense Mutation (SNP) | VAF 163/508 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SERPINB12 | c.350G>A p.R117K | Missense Mutation (SNP) | VAF 116/399 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC39A14 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 163/477 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC39A7 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 297/851 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- SLC7A10 | c.530G>A p.S177N | Missense Mutation (SNP) | VAF 109/323 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by muse, varscan2
- STIL | c.2069C>T p.S690L | Missense Mutation (SNP) | VAF 281/395 reads (71%) | SIFT tolerated (0.13); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- SUPT5H | c.3029G>A p.G1010D | Missense Mutation (SNP) | VAF 126/351 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- SV2A | c.1394C>T p.T465I | Missense Mutation (SNP) | VAF 144/409 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TACR1 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 171/524 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRIM58 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 277/726 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- TRIM64B | c.675G>A p.M225I | Missense Mutation (SNP) | VAF 127/870 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- TTLL13P | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 216/613 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TTN | c.21857G>A p.S7286N (on ENST00000591111; = p.S6359N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/355 reads (33%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WAS | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 157/219 reads (72%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF250 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 162/467 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ZNF519 | c.473del p.N158Ifs*3 | Frame Shift Del (DEL) | VAF 63/219 reads (29%) | called by mutect2, pindel, varscan2
- ACOX3 | c.900C>T p.S300= | Silent (SNP) | VAF 171/435 reads (39%) | called by muse, mutect2, varscan2
- ADAMTS18 | c.2331C>T p.I777= | Silent (SNP) | VAF 125/366 reads (34%) | catalogued as rs1349275933, COSV51398750; called by muse, mutect2, varscan2
- ANO4 | c.513C>T p.V171= (on ENST00000392977 / NM_001286615.2; = p.V136= on NM_178826.4) | Silent (SNP) | VAF 83/352 reads (24%) | called by muse, mutect2, varscan2
- AR | c.1821C>T p.F607= | Silent (SNP) | VAF 188/269 reads (70%) | called by muse, mutect2, varscan2
- ART5 | c.309G>A p.S103= | Silent (SNP) | VAF 205/608 reads (34%) | catalogued as rs779219965, COSV100731555; called by muse, mutect2, varscan2
- C8orf89 | c.357T>C p.P119= | Silent (SNP) | VAF 121/331 reads (37%) | called by muse, mutect2, varscan2
- CD226 | c.822C>T p.F274= | Silent (SNP) | VAF 94/275 reads (34%) | called by muse, mutect2
- CEP131 | c.2508G>A p.L836= (on ENST00000269392 / NM_001319228.2; = p.L833= on NM_014984.4) | Silent (SNP) | VAF 186/513 reads (36%) | catalogued as COSV53954623; called by muse, mutect2, varscan2
- CLEC16A | c.864C>T p.F288= | Silent (SNP) | VAF 80/405 reads (20%) | catalogued as rs1171899292; called by muse, mutect2, varscan2
- CLOCK | c.1659A>G p.E553= | Silent (SNP) | VAF 137/378 reads (36%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.3603C>T p.F1201= | Silent (SNP) | VAF 152/417 reads (36%) | catalogued as rs1306756593; called by muse, mutect2, varscan2
- CSMD1 | c.5604C>T p.P1868= (on ENST00000520002; = p.P1867= on NM_033225.6) | Silent (SNP) | VAF 114/327 reads (35%) | catalogued as rs1022910772, COSV59286713; called by muse, mutect2, varscan2
- CYFIP2 | c.3120G>A p.Q1040= (on ENST00000616178 / NM_001291722.2; = p.Q1015= on NM_014376.4) | Silent (SNP) | VAF 170/301 reads (56%) | called by muse, mutect2, varscan2
- CYP4F2 | c.72G>T p.L24= | Silent (SNP) | VAF 135/413 reads (33%) | called by muse, mutect2, varscan2
- DGKK | c.909C>T p.I303= | Silent (SNP) | VAF 147/218 reads (67%) | called by muse, mutect2, varscan2
- DPYS | c.567C>T p.A189= | Silent (SNP) | VAF 179/478 reads (37%) | called by muse, mutect2, varscan2
- EFCAB5 | c.4317C>T p.I1439= | Silent (SNP) | VAF 84/238 reads (35%) | called by muse, mutect2, varscan2
- ELK1 | c.243C>T p.F81= | Silent (SNP) | VAF 192/274 reads (70%) | catalogued as rs763088656, COSV55953832; called by muse, mutect2, varscan2
- FAM155A | c.1299C>T p.A433= | Silent (SNP) | VAF 148/484 reads (31%) | called by muse, mutect2
- FAM71B | c.522C>T p.L174= | Silent (SNP) | VAF 135/250 reads (54%) | catalogued as COSV100261917; called by muse, varscan2
- FAM71B | c.423C>T p.R141= | Silent (SNP) | VAF 140/244 reads (57%) | catalogued as rs769714278; called by muse, varscan2
- FRG2B | c.438G>A p.R146= | Silent (SNP) | VAF 216/910 reads (24%) | called by muse, varscan2
- GGT2 | c.156G>A p.E52= | Silent (SNP) | VAF 137/663 reads (21%) | catalogued as rs1331002021; called by muse, mutect2, varscan2
- GLP1R | c.147C>T p.S49= | Silent (SNP) | VAF 144/406 reads (35%) | called by muse, mutect2, varscan2
- GNA12 | c.711G>A p.K237= | Silent (SNP) | VAF 206/528 reads (39%) | catalogued as rs371474667; called by muse, mutect2, varscan2
- GNAT1 | c.396C>T p.I132= | Silent (SNP) | VAF 88/454 reads (19%) | catalogued as COSV50033532; called by muse, mutect2, varscan2
- HLA-DRA | c.528C>T p.L176= | Silent (SNP) | VAF 298/863 reads (35%) | called by muse, mutect2, varscan2
- ITGB4 | c.1293G>A p.K431= | Silent (SNP) | VAF 216/527 reads (41%) | catalogued as rs371350190; called by muse, mutect2, varscan2
- KCND3 | c.702C>T p.V234= | Silent (SNP) | VAF 390/560 reads (70%) | called by muse, mutect2, varscan2
- MAGEE2 | c.783C>T p.I261= | Silent (SNP) | VAF 185/263 reads (70%) | called by muse, mutect2, varscan2
- MERTK | c.642C>T p.F214= | Silent (SNP) | VAF 158/522 reads (30%) | called by muse, mutect2, varscan2
- MFSD2B | c.372C>T p.I124= | Silent (SNP) | VAF 169/446 reads (38%) | catalogued as rs766988877; called by muse, mutect2, varscan2
- MGAT5B | c.1656C>T p.F552= (on ENST00000569840 / NM_001199172.2; = p.F550= on NM_144677.3) | Silent (SNP) | VAF 220/627 reads (35%) | catalogued as COSV56931490; called by muse, mutect2, varscan2
- MUC12 | c.7977C>T p.I2659= (on ENST00000379442; = p.I2516= on NM_001164462.1) | Silent (SNP) | VAF 106/1922 reads (6%) | catalogued as rs1207028179; called by muse, mutect2
- MYH6 | c.252C>T p.F84= | Silent (SNP) | VAF 161/282 reads (57%) | catalogued as rs397516757, COSV62453045; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO9A | c.303G>A p.E101= | Silent (SNP) | VAF 164/494 reads (33%) | catalogued as rs780947548; called by muse, mutect2, varscan2
- NUP50 | c.426C>T p.S142= | Silent (SNP) | VAF 45/618 reads (7%) | called by muse, mutect2
- OR5B3 | c.453C>T p.F151= | Silent (SNP) | VAF 168/490 reads (34%) | catalogued as rs184127928, COSV58678514; called by muse, mutect2, varscan2
- PHEX | c.669C>T p.D223= | Silent (SNP) | VAF 138/209 reads (66%) | called by muse, mutect2, varscan2
- PLIN5 | c.1143C>T p.I381= | Silent (SNP) | VAF 184/574 reads (32%) | catalogued as COSV67850446; called by muse, mutect2, varscan2
- POTED | c.1722G>A p.L574= | Silent (SNP) | VAF 31/95 reads (33%) | called by muse, varscan2
- PRAG1 | c.2361G>A p.G787= | Silent (SNP) | VAF 194/567 reads (34%) | called by muse, varscan2
- PRAMEF19 | c.1275C>T p.V425= | Silent (SNP) | VAF 108/576 reads (19%) | called by muse, mutect2, varscan2
- PTPRK | c.4194G>A p.R1398= (on ENST00000368215 / NM_001291984.2; = p.R1399= on NM_002844.4) | Silent (SNP) | VAF 131/463 reads (28%) | catalogued as rs745368678; called by muse, mutect2, varscan2
- QRSL1 | c.1572C>T p.V524= | Silent (SNP) | VAF 114/351 reads (32%) | called by muse, mutect2, varscan2
- RAB33B | c.537T>C p.A179= | Silent (SNP) | VAF 175/515 reads (34%) | catalogued as rs750239564, COSV59777459; called by muse, mutect2, varscan2
- RTP5 | c.1599C>T p.C533= | Silent (SNP) | VAF 276/699 reads (39%) | catalogued as COSV100574785; called by muse, mutect2, varscan2
- SERTAD4 | c.144G>A p.Q48= | Silent (SNP) | VAF 178/473 reads (38%) | called by muse, mutect2, varscan2
- SHISA6 | c.945G>A p.K315= (on ENST00000409168 / NM_001173461.1; = p.K366= on NM_207386.4) | Silent (SNP) | VAF 81/239 reads (34%) | called by muse, mutect2, varscan2
- SLC45A1 | c.228G>A p.G76= | Silent (SNP) | VAF 296/425 reads (70%) | called by muse, mutect2, varscan2
- SPTLC3 | c.1047G>A p.R349= | Silent (SNP) | VAF 166/472 reads (35%) | called by muse, mutect2, varscan2
- TBC1D16 | c.63C>T p.T21= | Silent (SNP) | VAF 214/573 reads (37%) | called by muse, mutect2, varscan2
- TLR6 | c.906G>A p.T302= | Silent (SNP) | VAF 114/351 reads (32%) | catalogued as rs371809071; called by muse, mutect2, varscan2
- UBXN6 | c.708C>T p.P236= | Silent (SNP) | VAF 157/469 reads (33%) | catalogued as rs761580414, COSV100010922, COSV56675078; called by muse, mutect2, varscan2
- USP31 | c.2643C>T p.S881= | Silent (SNP) | VAF 170/473 reads (36%) | catalogued as rs1220306386; called by muse, mutect2, varscan2
- VPS13D | c.12630G>A p.A4210= | Silent (SNP) | VAF 260/380 reads (68%) | catalogued as rs146166812; called by muse, mutect2, varscan2
- VWDE | c.1653C>T p.I551= | Silent (SNP) | VAF 163/403 reads (40%) | called by muse, mutect2, varscan2
- WAS | c.1350C>T p.A450= | Silent (SNP) | VAF 156/219 reads (71%) | called by muse, mutect2, varscan2
- WDFY4 | c.2652G>A p.G884= | Silent (SNP) | VAF 192/485 reads (40%) | catalogued as rs1565182335; called by muse, mutect2, varscan2
- ZFYVE26 | c.4351C>T p.L1451= | Silent (SNP) | VAF 134/230 reads (58%) | called by muse, mutect2, varscan2
- ZNF257 | c.78G>A p.Q26= | Silent (SNP) | VAF 69/268 reads (26%) | catalogued as rs756254242, COSV71306617, COSV71306647; called by muse, mutect2, varscan2
- ZSCAN5C | c.1446C>T p.T482= | Silent (SNP) | VAF 172/464 reads (37%) | called by muse, mutect2, varscan2
- ADAM18 | c.522+18G>A | Intron (SNP) | VAF 91/226 reads (40%) | catalogued as rs779970792; called by muse, mutect2, varscan2
- C2orf16 | chr2:27572681 G>A | 5'Flank (SNP) | VAF 123/388 reads (32%) | called by muse, mutect2, varscan2
- FAAP100 | c.*619C>G | 3'UTR (SNP) | VAF 181/606 reads (30%) | called by muse, mutect2, varscan2
